Gene-level copy-number profile of tumor specimen HCM-BROD-0448-C15-06A from HCMI case HCM-BROD-0448-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IVB; Age at diagnosis: 78.6 years (28,714 days).
Specimen HCM-BROD-0448-C15-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Pleural Effusion; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f82f87af-0864-4df7-ae34-ed102610aa55.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0448-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/1b4a5e10-ae9b-45a1-a3e9-a5006754e891

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,899; copy number 2: 55,113; copy number 3: 904.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 46. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
